Gene-level copy-number profile of specimen HCM-SANG-0285-C18-85A from HCMI case HCM-SANG-0285-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0285-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 917e97dc-2531-4b11-8b2a-40118f6095a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0285-C18-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/b49ca97b-ac19-4803-8f7c-10f755322007

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 6; copy number 2: 56; copy number 3: 6; copy number 4: 43,116; copy number 5: 4,836; copy number 6: 4,746; copy number 7: 2,034; copy number 8: 2,526; copy number 9: 1,069.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,069 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,154,985–245,709,432, 1 gene, copy number 9 (within-gene range 8–9): KIF26B.
- chr1:245,614,773–246,507,312, 8 genes, copy number 9 (within-gene range 8–9): AC104462.2, AC104462.1, SMYD3, AC118555.1, SMYD3-AS1, CHCHD4P5, RNU6-1283P, SMYD3-IT1.
- chr8:74,798,784–145,066,685, 1,060 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
